Somatic mutation profile of tumor specimen TCGA-IM-A3U3-01A (aliquot TCGA-IM-A3U3-01A-11D-A22D-08) from TCGA case TCGA-IM-A3U3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 55.1 years (20,117 days).
Specimen TCGA-IM-A3U3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c80f623-4b78-4c49-b274-579c04ec5b06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IM-A3U3-10A (Blood Derived Normal), aliquot TCGA-IM-A3U3-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90981b92-86b7-4d62-bf9e-8c54d1031270

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 17, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB11 | c.3755A>G p.E1252G | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55593685; called by muse, mutect2
- ABCD1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as rs1373052080, COSV54385676; called by muse, mutect2, varscan2
- AL645922.1 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs776265184, COSV54961111; called by muse, mutect2, varscan2
- ARFGEF2 | c.3082C>T p.H1028Y | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64213025; called by muse, mutect2, varscan2
- ATPAF1 | c.673A>G p.I225V (on ENST00000574428; = p.I248V on NM_022745.4) | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV61305203; called by muse, mutect2, varscan2
- AZIN2 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV53858342; called by muse, varscan2
- CAB39L | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs149022536, COSV61713679; called by muse, mutect2, varscan2
- FAM161A | c.66C>G p.I22M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as COSV56766790; called by muse, mutect2, varscan2
- GOLGA1 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV63024186; called by muse, mutect2
- HIPK1 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.362); catalogued as COSV61248683; called by muse, mutect2
- NAP1L3 | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV59076158; called by muse, varscan2
- NAV3 | c.1617A>C p.Q539H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV57088142; called by muse, mutect2, varscan2
- RENBP | c.751G>C p.G251R | Missense Mutation (SNP) | VAF 65/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64170072; called by muse, mutect2, varscan2
- SLC41A3 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV59988785; called by muse, mutect2
- TMEM71 | c.493G>A p.D165N (on ENST00000523829 / NM_001382398.1; = p.D146N on NM_144649.3) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1421302913, COSV63457921; called by muse, mutect2
- TTN | c.14551C>A p.P4851T (on ENST00000591111; = p.P3924T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV60140596, COSV60408893; called by muse, mutect2
- TG | c.4690_4691del p.Q1564Vfs*8 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by pindel, varscan2
- CBLB | c.834C>A p.T278= | Silent (SNP) | VAF 14/228 reads (6%) | catalogued as COSV51429420; called by muse, mutect2
- DZIP3 | c.3108A>G p.R1036= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as COSV64312544; called by muse, mutect2, varscan2
